Somatic mutation profile of tumor specimen TARGET-20-PAPVDV-09A (aliquot TARGET-20-PAPVDV-09A-01D) from TARGET case TARGET-20-PAPVDV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.3 years (2,318 days).
Specimen TARGET-20-PAPVDV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dccd1d21-6901-458b-b75e-7dfc4ecbf0bf.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PAPVDV-14A (Bone Marrow Normal), aliquot TARGET-20-PAPVDV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0d73794-6bb6-46bd-ba15-fa73624b3646

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 42/198 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MET | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774779741, COSV59262341; called by muse, mutect2, varscan2
- ASXL2 | c.1271del p.P424Qfs*2 | Frame Shift Del (DEL) | VAF 64/252 reads (25%) | called by mutect2, pindel, varscan2
- BCOR | c.4052C>T p.T1351I (on ENST00000378444 / NM_001123385.2; = p.T1317I on NM_017745.6) | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- EZH2 | c.892+4A>C | Splice Region (SNP) | VAF 9/181 reads (5%) | called by muse, mutect2
